Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A7B3, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A7B3-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.
(B) BILATERAL PELVIC LYMPH NODES:
Seventeen lymph nodes, no tumor present (0/17).

Entire report and diagnosis completed by

CSCF ICD O-3
Adenocarcinoma acinar
path 8/40/13
Adenocarcinoma NOS
Site Prostate NOS 8/40/13
C61.9
JW 8/22/13

GROSS DESCRIPTION

- (A) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.
(B) BILATERAL PELVIC LYMPH NODES – An 8.0 x 6.5 x 1.0 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal 17 possible lymph nodes ranging from 0.2 x 0.2 x 0.1 cm – 4.0 x 0.8 x 0.6 cm.
SECTION CODE: Lymph nodes entirely submitted as follows: B1-B4, three possible lymph nodes in each; B5, two possible lymph nodes; B6, one possible lymph node sectioned; B7, B8, one possible lymph node sectioned; B9-B11, one possible lymph node sectioned.

CLINICAL HISTORY
Prostate cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5). (SEE COMMENT).

EXTENSIVE MULTIFOCAL EXTRAPROSTATIC EXTENSION PRESENT.

CARCINOMA INVOLVING RIGHT SEMINAL VESICLE.

Margins of resection free of tumor.

Left seminal vesicle and segments of vasa deferentia, no tumor present.

PERINEURAL AND LYMPHOVASCULAR INVASION PRESENT.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma, one in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the left anterolateral, left anterior, mid-anterior, right anterior, right anterolateral, right lateral, right posterolateral, right posterior, mid-posterior, left posterior and left posterolateral peripheral zone. This tumor focus measures 3.0 x 2.5 cm in the largest cross-sectional dimension and it is present in the three cross-sections of the prostate and extensively in the apex and base. This tumor focus exhibits extensive multifocal extraprostatic extension. Extraprostatic extension is present in the posterior apex, right posterolateral surface of the prostate, right superior neurovascular bundle region and in the base in the region anterior to the seminal vesicles. The tumor invades the right seminal vesicle including intra and extraprostatic portions. The margins of resection are free of tumor. The second tumor is located in the left transition zone. This tumor focus measures 0.6 x 0.5 cm in the largest cross-sectional dimension and it is present in two cross-sections. This tumor focus is of lower histologic grade and confined to the prostate. All margins of resection are free of tumor.

GROSS DESCRIPTION

(A) PROSTATE, SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (6.5 x 4.0 x 6.0 cm, 58.0 grams, post-fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate is abundant and more extensive than along the left side. A nodule is palpated on the right side of the prostate. Serial cross-sections demonstrate an area of tumor involving the right lateral, right posterolateral peripheral zone with extension into extraprostatic tissue involving the three cross-sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

Also included in the container is a detached fragment of tissue measuring 2.2 x 1.2 x 0.7 cm.

SECTION CODE: A1, detached fragment of tissue; A2-A5, right seminal vesicle and segment of right vas deferens from the base towards the tip; A6-A8, left seminal vesicle and segment of left vas deferens from the base towards the tip; A9-A10, prostatic base, right border; A11-A19, prostatic base, right posterior border; A20-A27, prostatic base, central portion; A28-A29, prostatic base, left border; A30-A33, prostatic base, left posterior border; A34-A36, apex anterior; A37-A39, apex left; A40-A44,

[page 3 of 3]
Specimen Date/Time:

apex posterior; A45-A47, apex right; A48, detached portions of margin of resection according to the specimen radiograph; A49-A62, sections of the three cross-sections of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (A51, 58, 61 and 62) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

Handwritten notes: 8/2/13, skin, NOS, No Tx

Source: NCI Genomic Data Commons file f7795e5a-fbaa-4c58-88f8-e8a58301e1dd (TCGA-KK-A7B3.45C687C3-52B9-4035-B916-777128B9AAE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).